Somatic mutation profile of tumor specimen TCGA-BF-AAOX-01A (aliquot TCGA-BF-AAOX-01A-11D-A397-08) from TCGA case TCGA-BF-AAOX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 83.0 years (30,318 days).
Specimen TCGA-BF-AAOX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b325474-52f8-4142-8497-16857180f63b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAOX-10A (Blood Derived Normal), aliquot TCGA-BF-AAOX-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a4088fc-aac2-4505-83f5-c6b57a908d63

The open-access MAF lists 1,506 somatic variants for this specimen: 979 protein-altering or splice-affecting, 487 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 897, Silent 487, Nonsense Mutation 51, Intron 20, Splice Site 14, RNA 13, Splice Region 8, In Frame Del 3, 5'Flank 3, Frame Shift Ins 2, 3'Flank 2, Frame Shift Del 2.

Variants (750 of 1,506; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908217, CM994288, COSV100800683, COSV100803453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5945G>A p.G1982E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111033250, CM091799, COSV68685675; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 38/129 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STAG1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1376334317, COSV52604028, COSV99364628; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA4 | c.1761G>A p.R587= | Splice Region (SNP) | VAF 12/19 reads (63%) | catalogued as COSV100933047; called by muse, mutect2, varscan2
- ABCC6 | c.1923A>C p.E641D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99228212; called by muse, mutect2, varscan2
- ABCC9 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53965797; called by muse, mutect2, varscan2
- ABLIM2 | c.1448C>T p.S483F (on ENST00000341937 / NM_001130084.2; = p.S432F on NM_032432.5) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV56405810; called by muse, mutect2, varscan2
- ABO | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV101505938; called by muse, mutect2, varscan2
- AC011448.1 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs368324977; called by muse, mutect2, varscan2
- ACAN | c.4528C>T p.P1510S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV100716857; called by muse, mutect2, varscan2
- ACTC1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as rs868254384, COSV51760596; called by muse, mutect2, varscan2
- ACTC1 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.848); catalogued as COSV99291650; called by muse, mutect2, varscan2
- ACTN3 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs1381590156, COSV101557810; called by muse, mutect2, varscan2
- ADAM11 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as rs1265032806, COSV99567177; called by muse, mutect2, varscan2
- ADAM18 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as rs866076661, COSV55845988; called by muse, mutect2, varscan2
- ADAM29 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286023799, COSV63661077; called by muse, mutect2, varscan2
- ADAMDEC1 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56477907; called by muse, mutect2, varscan2
- ADAT1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.096); catalogued as COSV100329119; called by muse, mutect2, varscan2
- ADCY4 | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1308295377, COSV100156231; called by muse, mutect2, varscan2
- ADGRB3 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV65420508; called by muse, mutect2, varscan2
- ADGRL2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041419067, COSV54651627; called by muse, mutect2, varscan2
- ADGRL2 | c.1912A>G p.T638A (on ENST00000370717 / NM_001366005.1; = p.T625A on NM_012302.4) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99587413; called by muse, mutect2, varscan2
- ADGRV1 | c.4516G>A p.D1506N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866466975, COSV101315553; called by muse, mutect2, varscan2
- ADGRV1 | c.6212C>T p.S2071F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV101315554; called by muse, mutect2, varscan2
- ADGRV1 | c.8558G>A p.G2853E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101315555, COSV67994488; called by muse, mutect2, varscan2
- ADGRV1 | c.9130C>T p.Q3044* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs1282761845, COSV67983279, COSV67985701; called by muse, mutect2, varscan2
- ADGRV1 | c.9556A>G p.T3186A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV101315556; called by muse, mutect2
- ADNP2 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100080591; called by muse, mutect2, varscan2
- ADORA1 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99704372; called by muse, mutect2, varscan2
- AHNAK | c.15823G>A p.G5275R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99945948; called by muse, mutect2, varscan2
- AHNAK2 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100316036; called by muse, mutect2, varscan2
- AIF1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.706); catalogued as COSV100559032; called by muse, mutect2, varscan2
- AKAP1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100027755; called by muse, mutect2, varscan2
- AKAP3 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV99961844; called by muse, mutect2, varscan2
- AKAP6 | c.5783C>T p.S1928L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55205105; called by muse, mutect2, varscan2
- AKR1B15 | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV101423351; called by muse, mutect2
- AKR1D1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs146708783, COSV54341545; called by muse, mutect2
- AKT3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV99793830, COSV99794426; called by muse, mutect2, varscan2
- AL121899.2 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101198400; called by muse, mutect2
- ALDH1A2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765361183, COSV51077923; called by muse, mutect2, varscan2
- ALDH8A1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as rs188652133, COSV55641793; called by muse, mutect2, varscan2
- ALDH8A1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV99664497; called by muse, mutect2, varscan2
- ALK | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV101201010, COSV101201418; called by muse, mutect2, varscan2
- ALPK2 | c.3154C>T p.P1052S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as COSV64495438; called by muse, mutect2, varscan2
- ALPK2 | c.1488G>A p.M496I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100864173; called by muse, mutect2, varscan2
- AMY1C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 25/291 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV100915189; called by muse, mutect2, varscan2
- ANK1 | c.3989G>A p.R1330K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV99224225; called by muse, mutect2, varscan2
- ANKRD24 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1209613879, COSV99517042; called by muse, mutect2, varscan2
- ANXA3 | c.948A>T p.L316F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99363566; called by muse, mutect2, varscan2
- AOC1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100710639; called by muse, mutect2, varscan2
- AOC2 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53824383; called by muse, mutect2, varscan2
- AOC2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519860; called by muse, mutect2, varscan2
- APOB | c.10801C>T p.Q3601* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99264038; called by muse, mutect2, varscan2
- APOL1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV100045946; called by muse, mutect2, varscan2
- ARAP2 | c.4114G>A p.D1372N | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100394229; called by muse, mutect2, varscan2
- ARAP2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs966987664, COSV58286766; called by muse, mutect2, varscan2
- ARF4 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100327131; called by muse, mutect2, varscan2
- ARHGAP18 | c.1494A>T p.E498D | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV100936037; called by muse, mutect2, varscan2
- ARHGAP30 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as COSV63517467; called by muse, mutect2, varscan2
- ARHGAP36 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99357333; called by muse, mutect2, varscan2
- ARHGAP5 | c.2828A>G p.N943S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV100565064, COSV61535013; called by muse, mutect2, varscan2
- ARHGEF10 | c.493C>T p.L165F (on ENST00000398564; = p.L141F on NM_014629.4) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as COSV50651122; called by muse, mutect2, varscan2
- ARHGEF18 | c.3205C>T p.P1069S (on ENST00000359920 / NM_001130955.2; = p.P965S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as rs1327699092, COSV100149118; called by muse, mutect2, varscan2
- ARID1B | c.6368C>T p.S2123L | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51652234; called by muse, mutect2, varscan2
- ARMC4 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1374412401, COSV53462533, COSV99518274; called by muse, mutect2, varscan2
- ARSG | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101477874; called by muse, mutect2, varscan2
- ASH1L | c.8738C>T p.P2913L (on ENST00000368346 / NM_001366177.2; = p.P2908L on NM_018489.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100853183; called by muse, mutect2, varscan2
- ASH1L | c.8737C>T p.P2913S (on ENST00000368346 / NM_001366177.2; = p.P2908S on NM_018489.3) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.968); catalogued as rs1176189509, COSV100853186; called by muse, mutect2, varscan2
- ASTN2 | c.1902G>A p.M634I (on ENST00000313400 / NM_001365069.1; = p.M583I on NM_014010.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV57823645; called by muse, mutect2
- ATG9A | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.108); catalogued as rs1157833854, COSV99521621; called by muse, mutect2, varscan2
- ATP13A1 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV99179105; called by muse, mutect2, varscan2
- ATP1A3 | c.121G>A p.E41K (on ENST00000545399 / NM_001256214.2; = p.E28K on NM_152296.5) | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV100132036; called by muse, mutect2, varscan2
- ATP2C2 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.922); catalogued as rs778257996, COSV99297544; called by muse, mutect2, varscan2
- ATP4A | c.2792C>T p.T931I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99382207; called by muse, mutect2, varscan2
- ATP4A | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52867261; called by muse, mutect2, varscan2
- ATP9B | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464975205, COSV100303011, COSV100303743; called by muse, mutect2, varscan2
- ATXN2 | c.1970A>T p.E657V (on ENST00000550104; = p.E497V on NM_002973.4) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV101112616, COSV66481968; called by muse, mutect2, varscan2
- BANK1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1472199600, COSV100535951; called by muse, mutect2, varscan2
- BBS5 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54753209; called by muse, mutect2, varscan2
- BCL6B | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431084194, COSV53427242; called by muse, mutect2, varscan2
- BIN1 | c.793G>A p.D265N (on ENST00000316724 / NM_001320642.1; = p.D234N on NM_004305.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs763298445, COSV99387618; called by muse, varscan2
- BLMH | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99913026; called by muse, mutect2, varscan2
- BMPER | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.936); catalogued as COSV99779042; called by muse, mutect2, varscan2
- BPIFC | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.076); catalogued as COSV55913642; called by muse, mutect2, varscan2
- BRMS1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV100240136; called by muse, mutect2, varscan2
- BTBD8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as COSV61546128; called by muse, mutect2, varscan2
- C10orf120 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61492912; called by muse, mutect2, varscan2
- C10orf71 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); catalogued as rs758472555, COSV60507579, COSV60509749; called by muse, mutect2, varscan2
- C12orf50 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170721797, COSV53893733; called by muse, mutect2, varscan2
- C12orf54 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs868088728, COSV58359933; called by muse, mutect2, varscan2
- C14orf39 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV100407338; called by muse, mutect2, varscan2
- C1orf127 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV65437313; called by muse, mutect2, varscan2
- C2orf16 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV68647031; called by muse, mutect2, varscan2
- C3 | c.4838G>A p.G1613E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.147); catalogued as rs141661874, COSV99836172; called by muse, mutect2, varscan2
- C5 | c.3641G>C p.R1214T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs150470491, COSV99797286, COSV99798886; called by muse, mutect2, varscan2
- C6 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1201346005, COSV99666626; called by muse, mutect2, varscan2
- CACNA1S | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100754731; called by muse, mutect2, varscan2
- CACNA2D1 | c.2678C>T p.A893V (on ENST00000356253 / NM_001366867.1; = p.A881V on NM_000722.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV62393077; called by muse, mutect2, varscan2
- CACNA2D1 | c.1820A>G p.Y607C (on ENST00000356253 / NM_001366867.1; = p.Y588C on NM_000722.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100666167; called by muse, mutect2, varscan2
- CACNB3 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV99974729; called by muse, mutect2, varscan2
- CACUL1 | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as rs1431068312, COSV100432437; called by muse, mutect2
- CALCA | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.835); catalogued as rs1219180885, COSV59028728; called by muse, mutect2, varscan2
- CAMK1D | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1435788333, COSV101123510; called by muse, mutect2, varscan2
- CAMKMT | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV101034209; called by muse, mutect2, varscan2
- CAND1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV73389562; called by muse, mutect2, varscan2
- CAPZA3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV56856262; called by muse, mutect2, varscan2
- CARMIL3 | c.1517A>G p.K506R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100549331; called by muse, mutect2, varscan2
- CASP14 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99692938; called by muse, mutect2, varscan2
- CCDC181 | c.1392G>A p.M464I (on ENST00000367806 / NM_001300969.1; = p.M463I on NM_021179.2) | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100250513; called by muse, mutect2, varscan2
- CCDC60 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100554721; called by muse, mutect2, varscan2
- CCDC88C | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs766262815, COSV101105230; called by muse, mutect2, varscan2
- CD163 | c.1068T>G p.N356K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.338); catalogued as COSV100775722; called by muse, mutect2, varscan2
- CD163L1 | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs764328944, COSV100549771; called by muse, mutect2, varscan2
- CD1B | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100939151; called by muse, mutect2, varscan2
- CD226 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99710850; called by muse, mutect2
- CD300LF | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100042656; called by muse, mutect2, varscan2
- CD46 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs746350474, COSV100522796; called by muse, mutect2, varscan2
- CDC42BPA | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100504012; called by muse, mutect2, varscan2
- CDH10 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.285); catalogued as COSV52570072; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1057C>T p.R353C (on ENST00000357886 / NM_001365728.1; = p.R339C on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267605888, COSV59426228; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621115; called by muse, mutect2, varscan2
- CDK8 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs1175776547, COSV67422919; called by muse, mutect2, varscan2
- CDYL2 | c.1299G>A p.W433* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs1447382699, COSV101629516; called by muse, mutect2
- CELA1 | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV53330199, COSV99529991; called by muse, mutect2, varscan2
- CENPE | c.2608T>C p.Y870H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99477181; called by muse, mutect2, varscan2
- CEP120 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as rs1414488743, COSV100070885; called by muse, mutect2, varscan2
- CFAP53 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs751078877, COSV68353065; called by muse, mutect2, varscan2
- CFAP53 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101274957; called by muse, mutect2, varscan2
- CFH | c.3610G>A p.G1204R | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV100808987; called by muse, mutect2, varscan2
- CFHR3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs772862546, COSV100807443; called by muse, mutect2, varscan2
- CHAF1B | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as COSV100023384; called by muse, mutect2, varscan2
- CHAF1B | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as rs776964270, COSV100023388; called by muse, mutect2, varscan2
- CHAMP1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1555379667, COSV100778735; called by muse, mutect2, varscan2
- CHD6 | c.7472C>T p.P2491L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs1310794292, COSV64690969; called by muse, mutect2, varscan2
- CHERP | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs1313761926, COSV99550040; called by muse, mutect2, varscan2
- CHGB | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100972926; called by muse, mutect2, varscan2
- CHL1 | c.1228A>C p.I410L (on ENST00000397491 / NM_001253387.1; = p.I426L on NM_006614.4) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as COSV99850327; called by muse, mutect2, varscan2
- CHST9 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52430345; called by muse, mutect2, varscan2
- CIR1 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV100564886; called by muse, mutect2, varscan2
- CLEC14A | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as COSV60562609; called by muse, mutect2, varscan2
- CMTR1 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs755381712, COSV100990852; called by muse, mutect2, varscan2
- CMYA5 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs551260526, COSV71405134, COSV71406357; called by muse, mutect2, varscan2
- CMYA5 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs865786564, COSV101483920; called by muse, mutect2, varscan2
- CMYA5 | c.5878G>A p.E1960K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV101483921, COSV71407325; called by muse, mutect2, varscan2
- CNGB3 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100181403, COSV100181425; called by muse, mutect2, varscan2
- CNNM2 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100881816; called by muse, mutect2, varscan2
- CNR2 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs752937607, COSV100991252; called by muse, varscan2
- CNTNAP2 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100663519; called by muse, mutect2, varscan2
- COL11A1 | c.2504G>A p.G835E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867124963, COSV62182610; called by muse, mutect2, varscan2
- COL27A1 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100620766; called by muse, mutect2, varscan2
- COL27A1 | c.2870C>T p.P957L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV100620767; called by muse, mutect2, varscan2
- COL4A2 | c.5060C>T p.S1687L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs746110125, COSV64629976; called by muse, mutect2, varscan2
- COL4A4 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631419; called by muse, mutect2
- COL4A4 | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295713821, CM1312563, COSV61637153; called by muse, mutect2, varscan2
- COL4A4 | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158615890, COSV100306365, COSV61631537; called by muse, mutect2, varscan2
- COL5A3 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs533616651, COSV99318322; called by muse, mutect2, varscan2
- COL5A3 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV99318324; called by muse, varscan2
- COL5A3 | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.025); catalogued as COSV99318326; called by muse, mutect2, varscan2
- COL6A3 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.815); catalogued as rs1255535853, COSV99796470; called by muse, mutect2, varscan2
- COPS4 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100018396; called by muse, mutect2, varscan2
- CPXM2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1210324555, COSV99581284; called by muse, mutect2, varscan2
- CRAT | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58878405; called by muse, mutect2, varscan2
- CREB3L3 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV99313925; called by muse, mutect2, varscan2
- CRTAM | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99911807, COSV99912208; called by muse, mutect2, varscan2
- CSF2RB | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99453348; called by muse, mutect2, varscan2
- CSF3R | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100117402; called by muse, mutect2, varscan2
- CSMD1 | c.2999T>C p.L1000P (on ENST00000520002; = p.L999P on NM_033225.6) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100144752; called by muse, mutect2, varscan2
- CSRP3 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99788165; called by muse, mutect2, varscan2
- CTLA4 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as CM1412308, COSV55592701; called by muse, mutect2, varscan2
- CTNNA2 | c.1753T>C p.F585L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100559583; called by muse, mutect2, varscan2
- CTNND1 | c.2783C>T p.P928L (on ENST00000399050 / NM_001085458.2; = p.P901L on NM_001331.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV100649862; called by muse, mutect2, varscan2
- CTNND2 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs1185078056, COSV100472834; called by muse, mutect2, varscan2
- CTR9 | c.3422A>G p.E1141G | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as COSV100797276; called by muse, mutect2, varscan2
- CUBN | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64720657; called by muse, mutect2, varscan2
- CUX1 | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782154947, COSV52895510; called by muse, mutect2, varscan2
- CUX2 | c.4123C>T p.P1375S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV99918836; called by muse, mutect2, varscan2
- CYLD | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV100282223; called by muse, mutect2, varscan2
- CYP2C19 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148593307; called by muse, mutect2, varscan2
- CYP39A1 | c.1338G>A p.Q446= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99241936; called by muse, mutect2, varscan2
- CYP3A4 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1366906328, COSV60504529; called by muse, mutect2, varscan2
- CYP3A5 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs930419944, COSV99769548; called by muse, mutect2, varscan2
- CYP4X1 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903286; called by muse, mutect2, varscan2
- DAB1 | c.1535C>T p.T512I (on ENST00000371231; = p.T479I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV100976174; called by muse, mutect2, varscan2
- DAW1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100005911; called by muse, mutect2, varscan2
- DAZAP1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV99245046; called by muse, varscan2
- DCC | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.905); catalogued as rs145690431, COSV59083434; called by muse, mutect2, varscan2
- DCST2 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs1191557053, COSV99791684; called by muse, mutect2, varscan2
- DCX | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV100576227; called by muse, mutect2, varscan2
- DDIT4L | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV99913825; called by muse, mutect2, varscan2
- DENND2C | c.1289A>G p.H430R (on ENST00000393274 / NM_001256404.2; = p.H373R on NM_198459.4) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV101283896; called by muse, mutect2, varscan2
- DENND2C | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs772944552, COSV67920142; called by muse, mutect2, varscan2
- DEPDC1 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100920218; called by muse, mutect2, varscan2
- DGCR8 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs767022640, COSV100707836; called by muse, mutect2, varscan2
- DGKI | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99932779; called by muse, mutect2, varscan2
- DGKK | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101052902; called by muse, mutect2, varscan2
- DHX37 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.74); catalogued as COSV100439044, COSV58134171; called by muse, mutect2, varscan2
- DLG2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54635405; called by muse, mutect2, varscan2
- DLGAP3 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs1446825282, COSV52396810; called by muse, mutect2, varscan2
- DLX5 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV99756263; called by muse, mutect2, varscan2
- DMAP1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762679185, COSV60001021; called by muse, mutect2, varscan2
- DMBT1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as rs756521132, COSV100352333; called by muse, mutect2, varscan2
- DMBT1 | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs370312495, COSV100352335; called by muse, mutect2, varscan2
- DMRT3 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs374319022, COSV51907430; called by muse, mutect2, varscan2
- DNAH11 | c.6202C>T p.R2068C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs745332741, COSV60940114; called by muse, mutect2, varscan2
- DNAH17 | c.8495G>A p.G2832E | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV101101611; called by muse, mutect2, varscan2
- DNAH2 | c.6646C>T p.P2216S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479864155, COSV66719250; called by muse, mutect2, varscan2
- DNAH3 | c.10308G>A p.M3436I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV99765421; called by muse, varscan2
- DNAH3 | c.10255G>A p.A3419T | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs769116142, COSV99765422; called by muse, varscan2
- DNAH5 | c.6718C>T p.P2240S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs867678270, COSV54225416, COSV54237531; called by muse, mutect2, varscan2
- DNAH7 | c.3335T>C p.L1112S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs202162878; called by muse, mutect2, varscan2
- DNAH8 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756498084, COSV59439392; called by muse, mutect2, varscan2
- DNAH8 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); catalogued as rs1196883272, COSV100543644; called by muse, mutect2, varscan2
- DNAH8 | c.8233C>T p.P2745S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs762468209, COSV59430323; called by muse, mutect2, varscan2
- DOCK3 | c.3380G>A p.R1127K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); catalogued as rs1156444497, COSV99809708; called by muse, mutect2, varscan2
- DOCK8 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs749747387, COSV101209824; called by muse, mutect2, varscan2
- DPYD | c.2841G>A p.M947I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64608807; called by muse, mutect2, varscan2
- DPYSL5 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99981881; called by muse, mutect2, varscan2
- DRC7 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs1384578698, COSV100395412; called by mutect2, varscan2
- DSC3 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1176722299, COSV64574222; called by muse, mutect2, varscan2
- DSC3 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1230194874, COSV100844545; called by muse, mutect2, varscan2
- DSG2 | c.1881G>A p.L627= | Splice Region (SNP) | VAF 22/59 reads (37%) | catalogued as rs754778907, COSV99852863; called by muse, mutect2, varscan2
- DSG2 | c.2271G>A p.M757I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99852867; called by muse, mutect2, varscan2
- DSG4 | c.3004C>T p.Q1002* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as rs267605160, COSV57394716; called by muse, mutect2, varscan2
- DTX4 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs368805854; called by muse, mutect2, varscan2
- DUSP1 | c.355T>C p.F119L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs772964123, COSV99495881; called by muse, varscan2
- DYRK1B | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100546456; called by muse, mutect2, varscan2
- DZIP1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs755372715, COSV61265778; called by muse, mutect2, varscan2
- ECD | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV100881369; called by muse, mutect2, varscan2
- EDC4 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs757992566, COSV100197494; called by muse, mutect2, varscan2
- EDEM2 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV100787992; called by muse, mutect2, varscan2
- EDN1 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 30/103 reads (29%) | catalogued as COSV65081016; called by muse, mutect2, varscan2
- EFHB | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99859209; called by muse, mutect2, varscan2
- EGFLAM | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs369346695, COSV59296529; called by muse, mutect2, varscan2
- EIF2D | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99662580; called by muse, mutect2, varscan2
- ELAPOR2 | c.2683C>T p.Q895* (on ENST00000450689 / NM_001142749.3; = p.Q728* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV99788311; called by muse, mutect2, varscan2
- ELMO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV60294929; called by muse, mutect2, varscan2
- ELMOD2 | c.22T>C p.F8L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV100062760; called by muse, mutect2, varscan2
- EMILIN2 | c.2214G>A p.W738* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV54420909, COSV99598207; called by muse, mutect2, varscan2
- EML5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs763457989, COSV61344205; called by muse, mutect2, varscan2
- ENC1 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as rs759810274, COSV100187947; called by muse, mutect2, varscan2
- EPB41L1 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52438925, COSV99149184; called by muse, mutect2, varscan2
- EPB41L4A | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV99812874; called by muse, mutect2, varscan2
- EPG5 | c.6598C>T p.P2200S | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99956639; called by muse, mutect2, varscan2
- EPS8L1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV99135748; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- ERC2 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV99881829; called by muse, varscan2
- ERN2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56833563; called by muse, mutect2, varscan2
- ERV3-1 | c.1102T>A p.Y368N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99275249; called by muse, mutect2, varscan2
- ESD | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs910058988, COSV101099094, COSV101099225; called by muse, mutect2, varscan2
- ETF1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV100860057; called by muse, mutect2, varscan2
- EXOC5 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1255225971, COSV100566990; called by muse, mutect2, varscan2
- EXOC6 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53319222, COSV53332686; called by muse, mutect2, varscan2
- EYS | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.361); catalogued as COSV100675812; called by muse, mutect2, varscan2
- F2R | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100058343; called by muse, mutect2, varscan2
- FABP6 | c.284_285insG p.F95Lfs*13 | Frame Shift Ins (INS) | VAF 19/32 reads (59%) | catalogued as COSV101221166; called by mutect2, pindel, varscan2
- FAM131B | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100577766; called by muse, mutect2, varscan2
- FAM13A | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs1360816553, COSV99982995; called by muse, mutect2, varscan2
- FAM151A | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs145547430; called by muse, mutect2, varscan2
- FAM161A | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs182330974, COSV56764247; called by muse, mutect2, varscan2
- FAM169A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1333118040, COSV65846875; called by muse, mutect2, varscan2
- FAM169A | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469647054, COSV100998313; called by muse, mutect2, varscan2
- FAM172A | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101232678; called by muse, mutect2, varscan2
- FAM184A | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.609); catalogued as COSV100137454; called by muse, mutect2, varscan2
- FAM214A | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV99957700; called by muse, mutect2, varscan2
- FAM91A1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100593462; called by muse, mutect2, varscan2
- FASTKD3 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99241373; called by muse, mutect2, varscan2
- FAT1 | c.11943T>A p.Y3981* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV101499134; called by muse, mutect2, varscan2
- FAT1 | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.259); catalogued as COSV71672174, COSV71674699; called by muse, mutect2, varscan2
- FAT4 | c.10411G>A p.D3471N | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100627449; called by muse, mutect2, varscan2
- FAT4 | c.13043G>A p.G4348E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627453, COSV100629208; called by muse, varscan2
- FAT4 | c.13084G>A p.A4362T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as COSV100627455; called by muse, varscan2
- FAT4 | c.13736G>A p.G4579E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58712451; called by muse, mutect2, varscan2
- FAXC | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.225); catalogued as COSV101067062; called by muse, mutect2, varscan2
- FBN2 | c.1646G>A p.C549Y | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1561427092, COSV99325483; called by muse, mutect2, varscan2
- FCRL5 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV62514817; called by muse, mutect2, varscan2
- FER1L6 | c.2619G>A p.W873* | Nonsense Mutation (SNP) | VAF 68/256 reads (27%) | catalogued as COSV67550687; called by muse, mutect2, varscan2
- FER1L6 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780197233, COSV67548091; called by muse, varscan2
- FGD2 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs764326106, COSV99235919; called by muse, varscan2
- FGF12 | c.358G>A p.G120R (on ENST00000454309 / NM_021032.5; = p.G58R on NM_004113.6) | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV53157828, COSV99279388; called by muse, mutect2, varscan2
- FGF14 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV65945068; called by muse, mutect2, varscan2
- FGF19 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99594278; called by muse, mutect2, varscan2
- FGFRL1 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377060032; called by muse, mutect2, varscan2
- FLG2 | c.5728G>A p.E1910K | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.527); catalogued as rs762744735, COSV101165636; called by muse, mutect2, varscan2
- FLT3 | c.1825A>T p.N609Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99607696; called by muse, mutect2, varscan2
- FMN2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1397813836, COSV60424392; called by muse, mutect2, varscan2
- FMN2 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.27); catalogued as rs778896753, COSV60421934, COSV60450150; called by muse, mutect2, varscan2
- FOXR2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs750738164, COSV100189427; called by muse, mutect2, varscan2
- FREM1 | c.6028C>T p.P2010S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs934520223, COSV66530902; called by muse, mutect2, varscan2
- FRMD3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100170726; called by muse, mutect2, varscan2
- FSHR | c.1359T>G p.S453R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436668; called by muse, mutect2, varscan2
- FSIP1 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.748); catalogued as COSV100617979; called by muse, mutect2, varscan2
- FSIP1 | c.848T>C p.L283S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617980; called by muse, mutect2, varscan2
- FUCA1 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100992130; called by muse, mutect2, varscan2
- GAB1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99528012; called by muse, mutect2, varscan2
- GAB4 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101271894; called by muse, mutect2, varscan2
- GABRA3 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750973085, COSV64795435; called by muse, mutect2, varscan2
- GAD2 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99392688; called by muse, mutect2
- GAD2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1328392915, COSV99392691; called by muse, mutect2, varscan2
- GALNT11 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs766822753, COSV100231663; called by muse, mutect2, varscan2
- GALNT14 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs867404786, COSV61103210; called by muse, mutect2, varscan2
- GALNT17 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212228242, COSV100352632; called by muse, mutect2, varscan2
- GALNT5 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as rs1371832237, COSV99374907; called by muse, mutect2, varscan2
- GBP2 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as rs189899416; called by muse, mutect2, varscan2
- GCM2 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101069446, COSV65275380; called by muse, mutect2, varscan2
- GDA | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs932604407, COSV52993612; called by muse, mutect2, varscan2
- GEM | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1356399304, COSV99891135; called by muse, mutect2, varscan2
- GHR | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.536); catalogued as CM940827, COSV50106432; called by muse, mutect2, varscan2
- GHRL | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99813893; called by muse, mutect2, varscan2
- GIMAP2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99785237; called by muse, mutect2, varscan2
- GIMAP7 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543594; called by muse, mutect2, varscan2
- GJB4 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100258309; called by muse, mutect2, varscan2
- GKN1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1259715183, COSV100933544, COSV65006725; called by muse, mutect2, varscan2
- GLI2 | c.3091G>A p.G1031R (on ENST00000361492 / NM_001374353.1; = p.G1048R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs897185156, COSV100082537; called by muse, mutect2
- GLI2 | c.4343G>T p.S1448I (on ENST00000361492 / NM_001374353.1; = p.S1465I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV100082539; called by muse, mutect2, varscan2
- GLRA2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV99490395; called by muse, mutect2, varscan2
- GLYATL1 | c.241G>A p.E81K (on ENST00000317391 / NM_001354699.1; = p.E112K on NM_080661.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs1187771539, COSV100265176; called by muse, mutect2, varscan2
- GLYATL2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99780235, COSV99780459; called by muse, mutect2, varscan2
- GMPPA | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs750437487, COSV100354533; called by muse, mutect2, varscan2
- GNAQ | c.738C>T p.N246= | Splice Region (SNP) | VAF 33/122 reads (27%) | catalogued as rs1449750349, COSV99680565; called by muse, mutect2, varscan2
- GPC5 | c.1327A>C p.N443H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100993002; called by muse, mutect2, varscan2
- GPR162 | c.1118G>A p.G373E (on ENST00000311268 / NM_019858.2; = p.G89E on NM_014449.2) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV51831367; called by muse, mutect2, varscan2
- GPR171 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs560925200, COSV56389795; called by muse, mutect2, varscan2
- GPR25 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.313); catalogued as rs892790384, COSV100421686; called by muse, mutect2, varscan2
- GPR84 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209640, COSV99909964; called by muse, mutect2, varscan2
- GPX5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV69079238; called by muse, mutect2, varscan2
- GRIA2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs752525141, COSV52391015, COSV52399091; called by muse, mutect2, varscan2
- GRIA3 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV99989254; called by muse, mutect2, varscan2
- GRIN2A | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.848); catalogued as COSV100408611; called by muse, mutect2, varscan2
- GRIN2B | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74205414; called by muse, mutect2, varscan2
- H3-4 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as rs768341466, COSV100797359; called by muse, mutect2, varscan2
- HAO2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs144704512; called by muse, mutect2, varscan2
- HAP1 | c.1780G>A p.E594K (on ENST00000310778 / NM_001367460.1; = p.E542K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100169448; called by muse, mutect2, varscan2
- HAUS8 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs774418271, COSV99505145; called by muse, mutect2, varscan2
- HAVCR2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs755156589, COSV57151819; called by muse, mutect2, varscan2
- HCFC1 | c.2179T>C p.S727P | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100128557; called by muse, mutect2, varscan2
- HCK | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52940431; called by muse, mutect2, varscan2
- HCN4 | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99983386; called by muse, mutect2, varscan2
- HDAC9 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1450802277, COSV101286492; called by muse, mutect2, varscan2
- HELB | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99921652; called by muse, mutect2, varscan2
- HFM1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV99645502, COSV99645966; called by muse, mutect2, varscan2
- HLX | c.1220T>A p.I407N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV100854473; called by muse, mutect2, varscan2
- HNF4A | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100291147; called by muse, mutect2, varscan2
- HOOK1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768278888, COSV100968998; called by muse, mutect2, varscan2
- HOXB3 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770485641, COSV57488620; called by muse, varscan2
- HS6ST3 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762458089, COSV100940097; called by muse, mutect2
- HTR1A | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as COSV60503362; called by muse, mutect2, varscan2
- HYDIN | c.6932C>T p.T2311I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV99992150; called by muse, mutect2, varscan2
- ICE1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99663964; called by muse, mutect2, varscan2
- ICE1 | c.5077C>T p.P1693S | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV56820512; called by muse, mutect2, varscan2
- IFIH1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99718453; called by muse, mutect2, varscan2
- IGF2BP1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1374084344, COSV51730173, COSV51736274, COSV99288339; called by muse, mutect2, varscan2
- IGFBP3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as COSV99298241; called by muse, mutect2, varscan2
- IGHG1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.934); catalogued as rs1364241800; called by muse, mutect2, varscan2
- IGHV1-18 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs546576232; called by muse, mutect2, varscan2
- IGSF10 | c.5272C>T p.H1758Y | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV56791613; called by muse, mutect2, varscan2
- IKZF2 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100563286; called by muse, mutect2, varscan2
- IL1R1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99292415; called by muse, mutect2, varscan2
- IL1R1 | c.899A>C p.E300A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV99292416; called by muse, mutect2, varscan2
- IL36G | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143518613; called by muse, mutect2, varscan2
- IMP4 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV99383623; called by muse, mutect2, varscan2
- IQGAP1 | c.3445A>G p.I1149V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs1381915231, COSV99184882; called by muse, mutect2, varscan2
- IQGAP2 | c.3422T>C p.V1141A | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99166784; called by muse, mutect2, varscan2
- IQSEC1 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as COSV99831441; called by muse, mutect2, varscan2
- IRAG2 | c.3193G>A p.E1065K (on ENST00000636465; = p.E110K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100611710; called by muse, mutect2, varscan2
- ISLR | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1338292376, COSV99997201; called by muse, mutect2, varscan2
- ITGA3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1429586302, COSV99143364; called by muse, mutect2, varscan2
- ITGA3 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760335644, COSV99143366; called by muse, mutect2, varscan2
- ITGA4 | c.557-1G>A p.X186_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as rs1285822411, COSV52002318, COSV99275835; called by muse, mutect2
- ITGA4 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1315003450, COSV51998379; called by muse, mutect2, varscan2
- ITGAD | c.3464C>T p.A1155V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1162554434, COSV54932517; called by muse, mutect2, varscan2
- ITGAX | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); catalogued as COSV99191494; called by muse, mutect2, varscan2
- JAG1 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99652534; called by muse, mutect2, varscan2
- JAK3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV71686122; called by muse, mutect2, varscan2
- KCNB2 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.192); catalogued as rs1480735255, COSV101578687; called by muse, mutect2, varscan2
- KCNH5 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as rs371757416; called by muse, mutect2, varscan2
- KCNH8 | c.1198A>C p.K400Q | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV100108801; called by muse, mutect2, varscan2
- KCNJ2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696234; called by muse, mutect2, varscan2
- KCNK5 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100851755; called by muse, mutect2, varscan2
- KCNK5 | c.465G>A p.L155= | Splice Region (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100851756; called by muse, mutect2, varscan2
- KCNT2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); catalogued as COSV99651977; called by muse, mutect2, varscan2
- KCNT2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV54070106; called by muse, mutect2, varscan2
- KDM2B | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV100997246; called by muse, mutect2, varscan2
- KDM2B | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV100997247; called by muse, mutect2, varscan2
- KDM4C | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV101184679; called by muse, mutect2, varscan2
- KDM5B | c.2267A>G p.N756S | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV99350167; called by muse, mutect2, varscan2
- KDM8 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs138715679; called by muse, mutect2, varscan2
- KDR | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99816878; called by muse, mutect2, varscan2
- KIAA1217 | c.3356C>T p.S1119F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV56817862; called by muse, mutect2, varscan2
- KIF21B | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV100143922; called by muse, mutect2, varscan2
- KIF26B | c.3607G>A p.D1203N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV63636893; called by muse, mutect2, varscan2
- KIF3B | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996337; called by muse, mutect2, varscan2
- KLF17 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100954842; called by muse, mutect2, varscan2
- KLHL1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV64770878; called by muse, mutect2, varscan2
- KLHL32 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.451); catalogued as COSV65113917; called by muse, mutect2, varscan2
- KLK13 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs757219149, COSV99335191; called by muse, mutect2, varscan2
- KLK15 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56825966; called by muse, mutect2, varscan2
- KLK4 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772602967, COSV100133548; called by muse, mutect2, varscan2
- KLK6 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV100037627; called by muse, mutect2, varscan2
- KNG1 | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs866217976, COSV99405197; called by muse, mutect2, varscan2
- KPRP | c.1553C>G p.S518C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1435550819, COSV100908668; called by muse, mutect2, varscan2
- KRBA1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); catalogued as rs577743172, COSV99752284; called by muse, mutect2, varscan2
- KRT33B | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV99290498; called by muse, mutect2, varscan2
- KRT6C | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99359869; called by muse, mutect2, varscan2
- KRT71 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99922001; called by muse, mutect2
- KRT8 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99509897; called by muse, mutect2, varscan2
- KRT82 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs755267742, COSV57786177; called by muse, mutect2, varscan2
- KRT83 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs144951378; called by muse, mutect2, varscan2
- LACTB | c.1415C>A p.T472K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV56055852, COSV99978845; called by muse, mutect2, varscan2
- LAMA3 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753783219, COSV100555706; called by muse, mutect2, varscan2
- LAMA3 | c.9326G>A p.G3109E (on ENST00000313654 / NM_198129.4; = p.G1500E on NM_000227.6) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99334069; called by muse, mutect2, varscan2
- LAMA5 | c.10667G>A p.G3556E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs958450940, COSV99438429; called by muse, mutect2, varscan2
- LAMB1 | c.4508T>C p.L1503P | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99740066; called by muse, mutect2, varscan2
- LAMB1 | c.2665T>A p.Y889N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV99740068; called by muse, mutect2, varscan2
- LAMC1 | c.3670C>T p.Q1224* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as COSV51185001, COSV99279116; called by muse, mutect2, varscan2
- LARP4B | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100295130; called by muse, mutect2, varscan2
- LARP6 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100150739; called by muse, mutect2, varscan2
- LCOR | c.3727C>T p.P1243S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV53715139, COSV53718587; called by muse, mutect2, varscan2
- LCT | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1340454714, COSV51543851; called by muse, mutect2, varscan2
- LEPR | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs372005711; called by muse, mutect2, varscan2
- LIG1 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs1409954502, COSV99618597; called by muse, mutect2, varscan2
- LILRA2 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV99252912; called by muse, mutect2, varscan2
- LILRA5 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs866247645, COSV56642126; called by muse, mutect2, varscan2
- LILRB5 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.499); catalogued as COSV100300131; called by muse, mutect2, varscan2
- LMAN1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99195318, COSV99195382; called by muse, mutect2, varscan2
- LMO7 | c.4705A>G p.T1569A (on ENST00000357063; = p.T1250A on NM_005358.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1324046109, COSV100412605; called by muse, mutect2, varscan2
- LONRF1 | c.776A>C p.Q259P | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV101238182; called by muse, mutect2, varscan2
- LRFN2 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1248891606, COSV57827695; called by muse, mutect2
- LRP1B | c.12641-2A>C p.X4214_splice | Splice Site (SNP) | VAF 13/43 reads (30%) | catalogued as COSV101253640; called by muse, mutect2, varscan2
- LRP1B | c.7783G>A p.E2595K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV101253641; called by muse, mutect2, varscan2
- LRP1B | c.4726C>T p.L1576F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67191549, COSV67202130; called by muse, mutect2, varscan2
- LRP1B | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV67203355; called by muse, mutect2, varscan2
- LRP2 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99786854; called by muse, mutect2, varscan2
- LRRC37B | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100496065, COSV58951149; called by muse, mutect2, varscan2
- LSM1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100258290, COSV60949349; called by muse, mutect2, varscan2
- LY6G5C | c.455G>A p.G152E (on ENST00000375863; = p.G77E on NM_025262.3) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101020809; called by muse, mutect2, varscan2
- LY96 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770987928, COSV99514308; called by muse, mutect2, varscan2
- MACF1 | c.9358C>T p.Q3120* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99241947; called by muse, mutect2, varscan2
- MAGEB2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100975603; called by muse, mutect2, varscan2
- MAGEC1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53570369; called by muse, mutect2, varscan2
- MAGEC1 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 80/117 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV53568967; called by muse, mutect2, varscan2
- MAGEL2 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58566643; called by muse, mutect2, varscan2
- MAGI2 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100833357; called by muse, mutect2, varscan2
- MAGI3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100288269, COSV56838781; called by muse, mutect2, varscan2
- MAMDC2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101015292; called by muse, mutect2, varscan2
- MAN2B1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as COSV99666725; called by muse, mutect2, varscan2
- MANSC1 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101115757, COSV67110604; called by muse, mutect2, varscan2
- MAP3K11 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs1380845904, COSV100482263, COSV100482362; called by muse, mutect2, varscan2
- MAP3K4 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100815098; called by muse, mutect2, varscan2
- MAP3K5 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62889721; called by muse, mutect2, varscan2
- MAP7 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100643774; called by muse, mutect2, varscan2
- MAPK15 | c.721+1G>A p.X241_splice | Splice Site (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100567722; called by muse, mutect2, varscan2
- MAPK15 | c.1461C>T p.V487= | Splice Region (SNP) | VAF 37/132 reads (28%) | catalogued as rs1554620119, COSV100567725; called by muse, mutect2, varscan2
- MARCHF10 | c.1853G>A p.R618K | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV100247893; called by muse, mutect2, varscan2
- MAST4 | c.4993G>A p.E1665K (on ENST00000403625 / NM_001164664.2; = p.E1476K on NM_015183.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.149); catalogued as rs772289937, COSV99843157; called by muse, varscan2
- MATN4 | c.1546G>A p.E516K (on ENST00000372754; = p.E475K on NM_003833.4) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | PolyPhen benign (0.388); catalogued as COSV100636911; called by muse, mutect2, varscan2
- MBD5 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101289963; called by muse, mutect2, varscan2
- MCTP1 | c.806G>A p.R269K | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.071); catalogued as COSV100386449; called by muse, mutect2, varscan2
- MECR | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs772261961, COSV55287293; called by muse, mutect2, varscan2
- MEDAG | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs992261307, COSV100995225; called by muse, mutect2, varscan2
- MEGF10 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs375925916; called by muse, mutect2, varscan2
- MFNG | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs1208325068, COSV100812858; called by muse, mutect2, varscan2
- MGAM | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs371920898; called by muse, mutect2, varscan2
- MGAM | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs868914154, COSV101527394; called by muse, mutect2, varscan2
- MGAM | c.3233C>T p.P1078L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV72074239; called by muse, mutect2, varscan2
- MGAM | c.5068G>A p.D1690N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV72074436; called by muse, mutect2
- MIPEP | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1214794201, COSV101193032; called by muse, mutect2, varscan2
- MKI67 | c.4006C>T p.P1336S | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.547); catalogued as rs759170836, COSV100896246, COSV64073601; called by muse, mutect2, varscan2
- MKX | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1401178413, COSV101008571; called by muse, mutect2, varscan2
- MME | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145687755, COSV64706075; called by muse, mutect2, varscan2
- MMP1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100187811; called by muse, mutect2, varscan2
- MOCS3 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724173; called by muse, mutect2, varscan2
- MPDZ | c.4331G>A p.G1444E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV100056269; called by muse, mutect2, varscan2
- MPO | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV51861375; called by muse, mutect2, varscan2
- MUC16 | c.37903G>A p.E12635K | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101197257; called by muse, mutect2, varscan2
- MUC16 | c.33818G>A p.S11273N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV101198451; called by muse, mutect2, varscan2
- MUC16 | c.29641G>A p.E9881K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.909); catalogued as COSV67441127; called by muse, mutect2, varscan2
- MUC16 | c.19316A>T p.K6439I | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as COSV101198458, COSV67463154; called by muse, mutect2, varscan2
- MUC16 | c.18607G>A p.D6203N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.065); catalogued as COSV101198459; called by muse, mutect2, varscan2
- MUC16 | c.11473C>T p.P3825S | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV67462075; called by muse, mutect2, varscan2
- MUC16 | c.10471C>T p.P3491S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.407); catalogued as rs767374429, COSV101198462; called by muse, mutect2, varscan2
- MUC16 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.094); catalogued as rs760649210, COSV101198463; called by muse, mutect2, varscan2
- MUC16 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs754448963, COSV101198464; called by muse, mutect2, varscan2
- MUC3A | c.8081C>T p.P2694L | Missense Mutation (SNP) | VAF 105/660 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100114098; called by muse, mutect2
- MXD1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV100037429; called by muse, mutect2
- MYB | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57196996, COSV57202207; called by muse, mutect2, varscan2
- MYBPC1 | c.300G>A p.M100I (on ENST00000550270 / NM_206820.2; = p.M125I on NM_002465.4) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100637782; called by muse, mutect2, varscan2
- MYH1 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56845217; called by muse, mutect2, varscan2
- MYH1 | c.2568G>A p.M856I | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs764002814, COSV99875106; called by muse, mutect2, varscan2
- MYH1 | c.1587+1G>A p.X529_splice | Splice Site (SNP) | VAF 31/86 reads (36%) | catalogued as COSV56844259; called by muse, mutect2, varscan2
- MYH2 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs763292061, COSV55432650; called by muse, mutect2, varscan2
- MYH7 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100805764; called by muse, mutect2, varscan2
- MYH7B | c.5486G>A p.R1829Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs763076910, COSV52682519; called by muse, mutect2, varscan2
- MYLK | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.242); catalogued as rs775461771, COSV100658605, COSV60613655; called by muse, mutect2, varscan2
- MYO16 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1186534652, COSV62746705; called by muse, mutect2, varscan2
- MYO1A | c.1952G>A p.G651E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100270658, COSV100270725; called by muse, mutect2, varscan2
- MYO5B | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99543843; called by muse, mutect2, varscan2
- MYT1L | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV101219206; called by muse, mutect2, varscan2
- NCAN | c.1361G>A p.S454N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV99386683; called by muse, mutect2, varscan2
- NDOR1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs1043196942, COSV100788869, COSV61287019; called by muse, mutect2, varscan2
- NEB | c.11249C>T p.S3750F | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV99416256; called by muse, mutect2, varscan2
- NEK1 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1454883910, COSV71456856; called by muse, mutect2, varscan2
- NEU4 | c.929G>A p.G310D (on ENST00000391969 / NM_001167602.3; = p.G322D on NM_080741.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs749242725; called by mutect2, varscan2
- NEXMIF | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.76); PolyPhen benign (0.047); catalogued as COSV99279885; called by muse, mutect2, varscan2
- NIBAN3 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV99961870; called by muse, mutect2, varscan2
- NLRP5 | c.3051G>A p.M1017I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66765557; called by muse, mutect2, varscan2
- NLRP7 | c.2920C>T p.P974S (on ENST00000340844 / NM_206828.3; = p.P1003S on NM_139176.3) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV60170964; called by muse, mutect2, varscan2
- NLRP7 | c.2275C>T p.H759Y (on ENST00000340844 / NM_206828.3; = p.H731Y on NM_139176.3) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV60170565; called by muse, mutect2, varscan2
- NLRP8 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV52587358; called by muse, mutect2, varscan2
- NMBR | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99237118; called by muse, mutect2, varscan2
- NME8 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99552899; called by muse, mutect2, varscan2
- NOTCH2 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99863059; called by muse, mutect2, varscan2
- NPAP1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV100274881, COSV61505529; called by muse, mutect2, varscan2
- NPAP1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.327); catalogued as rs747459205, COSV100274883; called by muse, mutect2, varscan2
- NPAS3 | c.1207G>A p.G403R (on ENST00000356141 / NM_001164749.2; = p.G371R on NM_022123.3) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100639805; called by muse, mutect2, varscan2
- NPY2R | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100279491; called by muse, mutect2, varscan2
- NPY5R | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100642666, COSV100642988; called by muse, mutect2, varscan2
- NPY5R | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV58451542; called by muse, mutect2, varscan2
- NR2C2AP | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100284442; called by muse, mutect2, varscan2
- NRP1 | c.2248C>A p.Q750K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.472); catalogued as COSV99587916; called by muse, mutect2, varscan2
- NRXN1 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100453706; called by muse, mutect2, varscan2
- NSD1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1026355239, COSV100728540; called by muse, mutect2, varscan2
- NSD1 | c.5509G>A p.A1837T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CS051692, COSV100728543; called by muse, mutect2, varscan2
- NSUN7 | c.380T>A p.I127N | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV100348927; called by muse, mutect2, varscan2
- NTN4 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs368121588; called by muse, mutect2, varscan2
- NUP153 | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs745957708, COSV100019918; called by muse, mutect2, varscan2
- OGDHL | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs771174825, COSV65102591; called by muse, mutect2
- OR10C1 | c.571G>A p.G191R (on ENST00000622521; = p.G189R on NM_013941.3) | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV101010800, COSV65824456; called by muse, mutect2, varscan2
- OR10H1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100612381; called by muse, mutect2, varscan2
- OR10H3 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV100008313; called by muse, mutect2, varscan2
- OR10J1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV101419801; called by muse, mutect2, varscan2
- OR10K2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs138581234; called by muse, mutect2, varscan2
- OR10W1 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV67720607, COSV67720767; called by muse, mutect2, varscan2
- OR10Z1 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as rs771297543, COSV100778950; called by muse, mutect2, varscan2
- OR12D2 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1487111242, COSV101011144; called by muse, mutect2, varscan2
- OR13C3 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV101053274; called by muse, mutect2, varscan2
- OR13C3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0); catalogued as COSV101053276; called by muse, mutect2
- OR13C8 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV58610917; called by muse, mutect2, varscan2
- OR13F1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100594696; called by muse, mutect2, varscan2
- OR2A5 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs149614119, COSV68738535; called by muse, mutect2, varscan2
- OR2B2 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100308056; called by muse, mutect2, varscan2
- OR2B2 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as COSV100308059; called by muse, mutect2, varscan2
- OR2D2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382715935, COSV100203746, COSV55058008; called by muse, mutect2, varscan2
- OR2J3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV101013568; called by muse, mutect2, varscan2
- OR2J3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as COSV65848776, COSV65849417; called by muse, mutect2, varscan2
- OR4A15 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.941); catalogued as rs772034737, COSV100123874; called by muse, mutect2, varscan2
- OR4C11 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1437645941, COSV56354997; called by muse, mutect2, varscan2
- OR4C13 | c.823A>C p.M275L | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV101634148; called by muse, mutect2, varscan2
- OR4D1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99274048; called by muse, mutect2, varscan2
- OR4E2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs369264275; called by muse, mutect2
- OR4K2 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100064191, COSV53850359; called by muse, varscan2
- OR4K2 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100064193; called by muse, mutect2, varscan2
- OR4K5 | c.482C>A p.S161* | Nonsense Mutation (SNP) | VAF 60/349 reads (17%) | catalogued as COSV100262193, COSV60002757; called by muse, mutect2, varscan2
- OR4P4 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1416828168, COSV100111595; called by muse, mutect2, varscan2
- OR51G1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775482982, COSV58968393; called by muse, mutect2, varscan2
- OR51Q1 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100332828; called by muse, mutect2, varscan2
- OR51V1 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as COSV58316057; called by muse, mutect2, varscan2
- OR52E6 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs903383149, COSV100259151; called by muse, mutect2, varscan2
- OR6Q1 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100109484; called by muse, mutect2
- OR6V1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769060424, COSV101389239; called by muse, mutect2, varscan2
- OR8B12 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV60911416; called by muse, mutect2, varscan2
- OR8B3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1352350871, COSV63541334; called by muse, mutect2, varscan2
- OR8H2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 103/373 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868862487, COSV57943241; called by muse, mutect2, varscan2
- OSMR | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV57092679; called by muse, mutect2, varscan2
- OTOF | c.3983G>A p.W1328* (on ENST00000272371 / NM_194248.3; = p.W561* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 43/127 reads (34%) | catalogued as COSV99716759; called by muse, mutect2, varscan2
- OTOF | c.2605G>A p.D869N (on ENST00000272371 / NM_194248.3; = p.D122N on NM_004802.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.305); catalogued as COSV55513000; called by muse, mutect2, varscan2
- OVCH2 | c.128G>A p.W43* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs1045945020, COSV101491860; called by muse, mutect2
- PADI1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100969011; called by muse, mutect2, varscan2
- PALB2 | c.3212T>C p.F1071S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99848144; called by muse, mutect2, varscan2
- PAPPA | c.3914C>T p.T1305I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100073079; called by muse, mutect2, varscan2
- PAPPA | c.4105G>A p.V1369M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073084; called by muse, mutect2, varscan2
- PARP12 | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99693872; called by muse, mutect2, varscan2
- PATJ | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100333342; called by muse, mutect2, varscan2
- PAXBP1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV99269084; called by muse, mutect2, varscan2
- PCDH11Y | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99290816; called by muse, mutect2, varscan2
- PCDH15 | c.4241G>A p.R1414Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs866920137, COSV57268337; called by muse, mutect2, varscan2
- PCDH17 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1486084656, COSV100931470, COSV100931812; called by muse, mutect2, varscan2
- PCDH18 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs868367262, COSV61267661; called by muse, mutect2, varscan2
- PCDH18 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs903210960, COSV61267146; called by muse, mutect2, varscan2
- PCDH19 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV55268409; called by muse, mutect2, varscan2
- PCDHAC1 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); catalogued as COSV53838362; called by muse, mutect2, varscan2
- PCDHB4 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); catalogued as COSV52019695; called by muse, mutect2, varscan2
- PCDHB8 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs143539367, COSV50773165; called by muse, mutect2, varscan2
- PCDHGC5 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.486); catalogued as COSV99338495; called by muse, mutect2, varscan2
- PCF11 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1473552860, COSV100017901; called by muse, mutect2, varscan2
- PCLO | c.14267G>A p.R4756K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs1483672930, COSV100428278; called by muse, mutect2
- PCLO | c.11491C>T p.R3831C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61626253; called by muse, mutect2, varscan2
- PDE1C | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58532532; called by muse, mutect2, varscan2
- PDIA3 | c.365-2A>G p.X122_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100294917; called by muse, mutect2, varscan2
- PEG3 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765630906, COSV55634529; called by muse, mutect2, varscan2
- PELI2 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50716394; called by muse, mutect2, varscan2
- PEX1 | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV99951931; called by muse, mutect2, varscan2
- PGLYRP3 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.446); catalogued as COSV99319521; called by muse, mutect2, varscan2
- PHF2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1460107467, COSV63678923; called by muse, mutect2, varscan2
- PHF21B | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as rs1168653906, COSV100503577; called by muse, mutect2, varscan2
- PHF21B | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); catalogued as COSV57555895; called by muse, mutect2, varscan2
- PHF3 | c.5273C>T p.S1758L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs983096966, COSV100012968, COSV100013821; called by muse, mutect2, varscan2
- PHYH | c.179T>C p.F60S | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV99538039; called by muse, mutect2, varscan2
- PIGO | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99956453; called by muse, mutect2, varscan2
- PIGR | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs1341487305, COSV100732448; called by muse, mutect2, varscan2
- PIK3AP1 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV100225558; called by muse, mutect2, varscan2
- PIK3CG | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as rs1263614656, COSV100782623; called by muse, mutect2
- PIP | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs750884957, COSV52120268; called by muse, mutect2, varscan2
- PIWIL1 | c.2375C>A p.T792K | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99806019, COSV99806084; called by muse, mutect2, varscan2
- PKD2 | c.2355G>T p.E785D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV52940763, COSV99416951; called by muse, mutect2, varscan2
- PKP2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.38); catalogued as rs1378578416, COSV99297319; called by muse, mutect2, varscan2
- PLA2G4A | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100820416; called by muse, varscan2
- PLCE1 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV99593805, COSV99593958; called by muse, mutect2, varscan2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by muse, varscan2
- PLEKHA2 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.143); catalogued as COSV101173347; called by muse, mutect2, varscan2
- PLG | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV100368902; called by muse, mutect2, varscan2
- PLXND1 | c.4822C>T p.L1608F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1462977700, COSV100139159; called by muse, mutect2, varscan2
- PNPLA3 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99336969; called by muse, mutect2, varscan2
- PNPLA5 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.14); catalogued as rs1181612327, COSV99336501; called by muse, varscan2
- POLN | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100526861; called by muse, mutect2, varscan2
- POLN | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs1207508792, COSV100526862; called by mutect2, varscan2
- POLR2E | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as rs1028649314, COSV99297424; called by muse, mutect2, varscan2
- PPAT | c.1128G>T p.L376F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99947102; called by muse, mutect2, varscan2
- PPFIA2 | c.3655T>A p.L1219I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100331936; called by muse, mutect2, varscan2
- PPIP5K1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769465108, COSV100613097; called by mutect2, varscan2
- PPL | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as rs764826268, COSV99277558; called by muse, mutect2, varscan2
- PPP1R13B | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs1212109793, COSV99157767; called by muse, mutect2, varscan2
- PPP1R3A | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV99492150; called by muse, mutect2, varscan2
- PPRC1 | c.4130C>T p.S1377F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99531371; called by muse, mutect2, varscan2
- PPRC1 | c.4855C>T p.R1619* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs1340538862, COSV99531377; called by muse, mutect2, varscan2
- PRAM1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as rs1417078219, COSV55311689, COSV99725687; called by muse, mutect2, varscan2
- PRAMEF4 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs762530862, COSV99339563; called by muse, mutect2, varscan2
- PRB2 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV66983024; called by muse, varscan2
- PRDM9 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1187228739, COSV99689805, COSV99689896; called by muse, mutect2, varscan2
- PRDM9 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99689897, COSV99691218; called by muse, mutect2, varscan2
- PRDM9 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs755568378, COSV57012182, COSV57015325, COSV99689899; called by muse, mutect2, varscan2
- PREX2 | c.4030G>A p.D1344N | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99905495; called by muse, mutect2, varscan2
- PRIMA1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as COSV100301162; called by muse, mutect2
- PRKD2 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs763752080, COSV99354134; called by muse, mutect2, varscan2
- PRKDC | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.376); catalogued as COSV100038810; called by muse, mutect2, varscan2
- PRKG1 | c.1182G>C p.L394F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV100907102, COSV100907160; called by muse, mutect2, varscan2
- PRKG2 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100019408; called by muse, mutect2, varscan2
- PRKN | c.386A>T p.K129M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as COSV100627767; called by muse, mutect2, varscan2
- PRLHR | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.226); catalogued as COSV99492678; called by muse, mutect2, varscan2
- PRLR | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs868847128, COSV99184233; called by muse, mutect2, varscan2
- PRPF18 | c.949-1G>A p.X317_splice | Splice Site (SNP) | VAF 28/101 reads (28%) | catalogued as COSV101058713, COSV66075909; called by muse, mutect2, varscan2
- PRPF18 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101058715; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1591C>T p.L531F (on ENST00000352766; = p.L452F on NM_181334.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV100424020; called by muse, mutect2
- PRSS12 | c.1687C>T p.H563Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV99627805, COSV99627818; called by muse, mutect2, varscan2
- PRSS3 | c.101C>T p.S34F (on ENST00000361005 / NM_007343.4; = p.S142F on NM_002771.3) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100725149; called by muse, mutect2, varscan2
- PRUNE2 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100944265; called by muse, mutect2, varscan2
- PSG1 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 54/198 reads (27%) | catalogued as rs748468852, COSV54945706, COSV99738898; called by muse, varscan2
- PSG5 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV100742577; called by muse, mutect2, varscan2
- PSKH2 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99405020; called by muse, mutect2, varscan2
- PSMC5 | c.1030C>A p.L344M | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV99856254; called by muse, mutect2, varscan2
- PTCHD4 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV100260278; called by muse, mutect2, varscan2
- PTH2R | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99782161; called by muse, mutect2, varscan2
- PTPRB | c.4403C>T p.S1468F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99716191; called by muse, mutect2
- PTPRC | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100722186; called by muse, mutect2, varscan2
- PTPRC | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100722188; called by muse, mutect2, varscan2
- PTPRD | c.3239C>T p.S1080L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV61930009; called by muse, mutect2, varscan2
- PTPRD | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100643725, COSV61963521; called by muse, mutect2, varscan2
- PTPRD | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100643726, COSV61925879; called by muse, mutect2, varscan2
- PTPRD | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100643728; called by muse, mutect2, varscan2
- PTPRO | c.2573G>A p.G858D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.371); catalogued as COSV99839918; called by muse, mutect2, varscan2
- PTPRT | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs371433526; called by muse, mutect2, varscan2
- PTPRT | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV100625670; called by muse, mutect2, varscan2
- PTPRU | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100111884; called by muse, mutect2, varscan2
- PTPRU | c.3671C>T p.S1224F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100111887; called by muse, mutect2, varscan2
- PUS7L | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61261871; called by muse, mutect2, varscan2
- PVRIG | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1386584052, COSV52781960, COSV99443718; called by muse, mutect2
- QRICH2 | c.2149C>T p.Q717* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV99428851; called by muse, mutect2, varscan2
- RAG2 | c.1295C>G p.P432R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753677011, CM1514431, COSV100271123; called by muse, mutect2, varscan2
- RANBP3L | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs745462557, COSV56956392; called by muse, mutect2, varscan2
- RAPGEF4 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1199801794, COSV99909963; called by muse, mutect2, varscan2
- RARB | c.242C>T p.P81L (on ENST00000383772 / NM_001290216.2; = p.P74L on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as COSV100412177, COSV100412211; called by muse, mutect2, varscan2
- RASAL2 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862452; called by muse, mutect2, varscan2
- RASGRP3 | c.2044G>A p.E682K (on ENST00000402538 / NM_001349975.2; = p.E681K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV101274703; called by muse, mutect2, varscan2
- RASSF9 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100771237; called by muse, mutect2, varscan2
- RBMS2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100008394; called by muse, mutect2, varscan2
- RBMXL2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60978535; called by muse, varscan2
- RBP5 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs187594426, COSV99866616; called by muse, mutect2, varscan2
- RECQL5 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100511667; called by muse, mutect2, varscan2
- REG3G | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV99709261; called by muse, mutect2, varscan2
- RELN | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58997209; called by muse, mutect2, varscan2
- RESF1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57020011; called by muse, mutect2, varscan2
- RESF1 | c.2599C>T p.H867Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100440141; called by muse, mutect2, varscan2
- RET | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs200956659, COSV100392655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGS11 | c.1054G>A p.D352N (on ENST00000397770 / NM_183337.3; = p.D331N on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.932); catalogued as COSV99395676; called by muse, mutect2, varscan2
- RGS22 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100693034; called by muse, mutect2, varscan2
- RHPN2 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1568318216, COSV99577132; called by muse, mutect2, varscan2
- RIMBP2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99898592; called by muse, mutect2, varscan2
- RLF | c.2349T>G p.S783R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV101035128; called by muse, mutect2, varscan2
- RNF165 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs368560170, COSV99491356; called by muse, mutect2, varscan2
- RNF17 | c.3713G>A p.R1238K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.969); catalogued as COSV99692418; called by muse, mutect2, varscan2
- RNF185 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 112/197 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99839648; called by muse, mutect2, varscan2
- ROBO2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.233); catalogued as COSV100164718; called by muse, mutect2, varscan2
- ROBO4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769202799, COSV100127348; called by muse, mutect2, varscan2
- RPAP1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV100426983; called by muse, mutect2, varscan2
- RPS6KC1 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100873792; called by muse, mutect2, varscan2
- RRP7A | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100543742; called by muse, mutect2, varscan2
- RTF1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV101047631; called by muse, mutect2, varscan2
- RTN4IP1 | c.920A>T p.N307I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100954119; called by muse, mutect2, varscan2
- RUNX1T1 | c.712G>A p.E238K (on ENST00000265814 / NM_001198628.1; = p.E211K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs746997350, COSV56139578; called by muse, mutect2, varscan2
- RYR1 | c.9868G>A p.E3290K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs112151058, CM091769, COSV100614823; called by muse, mutect2, varscan2
- RYR3 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212106; called by mutect2, varscan2
- S100A7A | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as rs765575828, COSV61330896; called by muse, mutect2, varscan2
- SALL2 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1472574829, COSV100444183, COSV58102417; called by muse, mutect2, varscan2
- SALL4 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV53854085, COSV99409252; called by muse, mutect2, varscan2
- SCAF8 | c.3385C>T p.R1129* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV65792102; called by muse, mutect2, varscan2
- SCAPER | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100237451; called by muse, varscan2
- SCARB2 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99357829; called by muse, mutect2, varscan2
- SCGB1D1 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100086645; called by muse, mutect2, varscan2
- SCGB2A1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.018); catalogued as COSV55276886; called by muse, mutect2, varscan2
- SCLT1 | c.990T>G p.I330M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV99827694; called by muse, mutect2, varscan2
- SCN11A | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100181044; called by muse, mutect2, varscan2
- SCN7A | c.4642C>T p.P1548S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101313110; called by muse, varscan2
- SCN7A | c.4571G>A p.R1524K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101313111; called by muse, varscan2
- SCN7A | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV69272273; called by muse, mutect2, varscan2
- SCN9A | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383119918, COSV100311728; called by muse, mutect2, varscan2
- SCN9A | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311729; called by muse, mutect2, varscan2
- SCUBE3 | c.1635A>T p.K545N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99234046; called by muse, mutect2, varscan2
- SDK2 | c.4682G>A p.G1561E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV101166993; called by muse, mutect2, varscan2
- SDK2 | c.3595C>T p.P1199S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465452863, COSV101166996; called by muse, mutect2
- SEC14L4 | c.74A>T p.D25V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99742727; called by muse, mutect2, varscan2
- SEC31A | c.3337C>T p.P1113S (on ENST00000355196 / NM_001318120.1; = p.P1074S on NM_016211.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52344823; called by muse, mutect2, varscan2
- SEC31B | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100947235; called by muse, mutect2, varscan2
- SELE | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100324550; called by muse, mutect2, varscan2
- SELL | c.1014G>A p.M338I (on ENST00000650983; = p.M325I on NM_000655.5) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1416767802; called by mutect2, varscan2
- SEMA4D | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as COSV100358020; called by muse, mutect2, varscan2
- SEMA5A | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV101227302, COSV66800825; called by muse, mutect2, varscan2
- SERPINB11 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1487853220, COSV101236151; called by muse, mutect2, varscan2
- SERPINB3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV99379636; called by muse, mutect2, varscan2
- SERPINB5 | c.1047T>G p.N349K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101237615; called by muse, mutect2, varscan2
- SETBP1 | c.3250C>A p.P1084T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV56316929, COSV99952297; called by muse, mutect2
- SETD2 | c.5647A>T p.I1883F | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57432163; called by muse, mutect2, varscan2
- SEZ6L | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs762219064, COSV50659948; called by muse, mutect2, varscan2
- SFXN5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs768905463, COSV99728934; called by muse, mutect2, varscan2
- SGSM1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV101240488, COSV101240775; called by muse, mutect2, varscan2
- SH3GL2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101014075; called by muse, mutect2, varscan2
- SH3RF3 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389916001, COSV100512454; called by muse, mutect2, varscan2
- SIDT1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1342424508, COSV99333272; called by muse, mutect2, varscan2
- SIDT1 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.369); catalogued as COSV99333275; called by muse, mutect2, varscan2
- SIGLEC6 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as rs199951067, COSV100585195; called by muse, mutect2, varscan2
- SLAMF6 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as COSV63588416; called by muse, mutect2, varscan2
- SLC11A2 | c.1540C>T p.L514F (on ENST00000394904 / NM_001379455.1; = p.L485F on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100015162, COSV50370805; called by muse, mutect2, varscan2
- SLC12A2 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as rs753799701, COSV52469577, COSV99320649; called by muse, mutect2, varscan2
- SLC13A1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.186); catalogued as COSV99520522; called by muse, mutect2, varscan2
- SLC13A1 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99520524; called by muse, mutect2, varscan2
- SLC14A2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs267605187, COSV99675141; called by muse, mutect2, varscan2
- SLC16A9 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101264334; called by muse, mutect2, varscan2
- SLC17A1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99765620; called by muse, varscan2
- SLC17A8 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.449); catalogued as rs199746996, COSV100035263, COSV60124300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A2 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1211022477, COSV100870941; called by muse, mutect2, varscan2
- SLC22A2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs1188532450, COSV65265906; called by muse, mutect2, varscan2
756 further variants in this file (229 protein-altering or splice-affecting, 487 silent, 40 other) are not listed here.
